CCDI case PBBJJE — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/9df732d8-2397-4d06-811c-455bee3380f4

Demographics
Sex at birth: female; Race: black or african american; Vital status: Alive.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Overlapping lesion of brain and central nervous system; Age at diagnosis: 11.9 years (4,329 days).

Biospecimens (3 samples)
- Sample 0DA2YI: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DA2YJ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DA2YK: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
